CCDI case PBBSSM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2ceb5c46-aa3c-4733-b7d2-4ed6a0e00ddf

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.4 years (2,333 days).

Biospecimens (3 samples)
- Sample 0DFSQN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFSS4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFSSJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
